Somatic mutation profile of tumor specimen 0DAEHR from CCDI case PBBIDF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,283 days).
Specimen 0DAEHR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92c5410a-f9e5-4378-9e2d-a818d8d5e10c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAEHE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f1ee1d6-a290-4ebc-82e6-8797c5eb4a4a

The open-access MAF lists 17 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 5, Silent 4, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMKK2 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 91/547 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1437886558; called by muse, mutect2, varscan2
- CD101 | c.1589T>A p.I530N | Missense Mutation (SNP) | VAF 65/580 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs756345822; called by muse, mutect2, varscan2
- FAM133A | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 82/2270 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL18R1 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 76/746 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SBK1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 39/638 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYNPO2L | c.2767G>A p.E923K (on ENST00000394810 / NM_001114133.3; = p.E699K on NM_024875.5) | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2
- FLNA | c.1389G>A p.V463= | Silent (SNP) | VAF 57/409 reads (14%) | called by muse, mutect2, varscan2
- RBM26 | c.900G>A p.K300= | Silent (SNP) | VAF 42/1172 reads (4%) | called by muse, mutect2
- SH2D4B | c.1239G>A p.E413= (on ENST00000646907; = p.V339I on NM_207372.2) | Silent (SNP) | VAF 88/1048 reads (8%) | catalogued as rs1256631596; called by muse, mutect2
- ZNF343 | c.573G>A p.R191= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as rs749730818; called by muse, mutect2, varscan2
- C9orf85 | c.323+1277A>G | Intron (SNP) | VAF 8/95 reads (8%) | catalogued as rs1446441319, COSV58253961; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/133 reads (9%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- CCDC68 | c.346-56G>A | Intron (SNP) | VAF 20/146 reads (14%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 13/122 reads (11%) | catalogued as COSV99987084; called by muse, varscan2
- LRRC63 | c.*79T>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- SGPL1 | c.-4G>A | 5'UTR (SNP) | VAF 33/578 reads (6%) | catalogued as COSV64592491; called by muse, mutect2
